HCMI case HCM-BROD-0041-C64 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/819b41c2-1aa4-4a98-959f-096fd3df1446

Demographics
Sex at birth: female; Race: white; Year of birth: 2009; Vital status: Alive.

Diagnoses (1)
1. Nephroblastoma, NOS: ICD-O-3 morphology code: 8960/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 7.3 years (2,655 days); Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Prior treatment: No; COG renal stage: Stage IV; Sites of involvement: Lung, NOS; Wilms tumor histologic subtype: Unfavorable.
   Pathology details: Anaplasia present: Yes; Anaplasia present type: Diffuse.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Etoposide + Ifosfamide; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Regimen or line of therapy: ICE; Days to treatment start: 0 days; Days to treatment end: 273 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin Hydrochloride + Vincristine; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 0 days; Days to treatment end: 273 days.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 0 days; Days to treatment end: 1 day.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (3 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 0 days.
- Days to follow up: 911 days (2.5 years); Disease response: Complete Response; Progression or recurrence: No.
- Follow-up contact recording only the day: day 485.

Other clinical attributes
- Timepoint category: Initial Diagnosis; BMI: 15.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-BROD-0041-C64-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-BROD-0041-C64-01A-01-S1-HE: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-BROD-0041-C64-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0041-C64-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 2D Modified Conditionally Reprogrammed Cells; Preservation method: Frozen; Passage count: 19.
- Sample HCM-BROD-0041-C64-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Adherent Cell Line; Preservation method: Frozen.
